Somatic mutation profile of tumor specimen TCGA-XE-AAOF-01A (aliquot TCGA-XE-AAOF-01A-11D-A435-10) from TCGA case TCGA-XE-AAOF, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 50.6 years (18,490 days).
Specimen TCGA-XE-AAOF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcef6b72-6769-4732-9a87-6b099d17745c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAOF-10A (Blood Derived Normal), aliquot TCGA-XE-AAOF-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f241b8d0-38fe-459b-bf1a-6fac4e97be3f

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 3, Silent 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- HEPHL1 | c.625del p.E209Kfs*4 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs1285515342; called by mutect2, pindel, varscan2
- LRRC57 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs548606804; called by muse, mutect2, varscan2
- STAT3 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1462777520; called by muse, mutect2, varscan2
- UTRN | c.8575C>T p.R2859C | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748581554, COSV62309423; called by muse, mutect2, varscan2
- CAVIN4 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DUOX2 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KDM3B | c.2831+2T>C p.X944_splice | Splice Site (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- MACF1 | c.11282C>T p.S3761L (on ENST00000372915; = p.S1694L on NM_012090.5) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, varscan2
- MCM3AP | c.1483C>G p.H495D | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MTA3 | c.265A>G p.R89G | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- NUP88 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- PLXNC1 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A5 | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- STAB1 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.604); called by muse, mutect2
- TAF7 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- KCNAB1 | c.702G>A p.A234= (on ENST00000490337 / NM_172160.3; = p.A223= on NM_003471.3) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs370190413; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+12480G>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- INTS2 | c.-46T>C | 5'UTR (SNP) | VAF 10/95 reads (11%) | catalogued as rs776596264; called by muse, mutect2, varscan2
- MRRF | c.459+486T>C | Intron (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- PRMT7 | c.1576-45del | Intron (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
